Somatic mutation profile of tumor specimen C3N-00299-02 (aliquot CPT0008630006) from CPTAC case C3N-00299, project CPTAC-3 (Lip — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 54.4 years (19,881 days).
Specimen C3N-00299-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33ead913-285f-45b1-8f47-4f7a6ddc07b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00299-31 (Blood Derived Normal), aliquot CPT0008670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e913e128-f2fd-46fd-8c7e-b15e5c40ea83

The open-access MAF lists 1,351 somatic variants for this specimen: 792 protein-altering or splice-affecting, 382 silent, 177 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 712, Silent 382, Intron 86, Nonsense Mutation 40, RNA 23, 3'UTR 22, 5'Flank 18, 5'UTR 16, Splice Region 15, Splice Site 13, 3'Flank 11, Frame Shift Del 5.

Variants (750 of 1,351; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 291/649 reads (45%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- CNGB3 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs121918344, CM001816; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 131/367 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 89/260 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519978, COSV52675559, COSV52751154, COSV52796306, COSV53037181; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13846C>T p.P4616S | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1376055144, COSV68943888; called by muse, mutect2, varscan2
- ABCA2 | c.3607C>T p.R1203C (on ENST00000614293; = p.R1173C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs374388910; called by muse, mutect2, varscan2
- ABCG8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/186 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1365569134; called by muse, mutect2, varscan2
- AC008397.2 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as rs148755672, COSV53204890; called by muse, mutect2, varscan2
- ACO1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs537741206, COSV59385166; called by muse, varscan2
- ACOXL | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as COSV101093737; called by muse, mutect2, varscan2
- ADAD1 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs959210665, COSV99636109; called by muse, mutect2, varscan2
- ADAM32 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65953070; called by muse, mutect2, varscan2
- ADAM9 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 79/601 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65963048; called by muse, mutect2, varscan2
- ADAMTS10 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs868925775; called by muse, mutect2, varscan2
- ADAMTS14 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV100941447; called by muse, mutect2, varscan2
- ADGRF5 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs750917822; called by muse, mutect2, varscan2
- ADGRL3 | c.360G>A p.M120I (on ENST00000506720 / NM_001322402.2; = p.M52I on NM_015236.6) | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868682069, COSV72267516; called by muse, mutect2, varscan2
- ADORA3 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 69/384 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV99598686; called by muse, mutect2, varscan2
- ADSS1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761679828; called by muse, mutect2
- AKR1C8P | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs782303060; called by muse, mutect2, varscan2
- ALB | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV55735709; called by muse, mutect2, varscan2
- AMZ1 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as rs867766709; called by muse, mutect2, varscan2
- ANGPT1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52454841; called by muse, mutect2, varscan2
- ANKRD30A | c.1549C>T p.P517S (on ENST00000611781; = p.P461S on NM_052997.2) | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.968); catalogued as rs760588501; called by muse, mutect2, varscan2
- ANKRD30A | c.2960G>A p.G987E (on ENST00000611781; = p.G931E on NM_052997.2) | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as COSV64620926, COSV64623054; called by muse, mutect2
- ANKUB1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1352959259; called by muse, mutect2
- AP1G1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs770148749, COSV55488248; called by muse, mutect2, varscan2
- APOB | c.8218G>A p.E2740K | Missense Mutation (SNP) | VAF 68/466 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV51931518; called by muse, mutect2, varscan2
- APOB | c.6227C>T p.T2076I | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs371068679; called by muse, mutect2, varscan2
- APOL3 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 69/490 reads (14%) | PolyPhen benign (0.005); catalogued as COSV100652111; called by muse, mutect2, varscan2
- ARHGAP27 | c.1970C>T p.P657L (on ENST00000428638 / NM_001282290.1; = p.P316L on NM_199282.3) | Missense Mutation (SNP) | VAF 60/307 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV65358425; called by muse, mutect2, varscan2
- ARHGEF15 | c.2092G>A p.V698I | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs762341051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARL5A | c.421T>C p.F141L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV54470964; called by muse, mutect2, varscan2
- ARMC5 | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as rs1219597251, COSV51655190; called by muse, mutect2, varscan2
- ASAP3 | c.2393C>T p.S798F | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV60878629; called by muse, mutect2, varscan2
- ATP10A | c.3404C>T p.P1135L | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as rs138925689; called by muse, mutect2, varscan2
- ATP13A5 | c.2320-1G>A p.X774_splice | Splice Site (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100665206; called by muse, mutect2, varscan2
- ATP6V0A4 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as rs200954029, COSV59474907; called by muse, mutect2, varscan2
- BANK1 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1481097757; called by muse, mutect2, varscan2
- BAZ2A | c.4670C>T p.S1557F | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs1233068882; called by muse, mutect2, varscan2
- BICD1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as COSV55678552; called by muse, mutect2, varscan2
- C1orf127 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.107); catalogued as rs1232303530; called by muse, mutect2, varscan2
- C2CD3 | c.5215C>T p.Q1739* | Nonsense Mutation (SNP) | VAF 59/383 reads (15%) | catalogued as COSV100486502; called by muse, mutect2, varscan2
- C6orf118 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.005); catalogued as COSV57813500; called by muse, mutect2, varscan2
- CACNA1E | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs986188761, COSV62406496, COSV62407370; called by muse, mutect2, varscan2
- CALHM5 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330166502; called by muse, mutect2, varscan2
- CARMIL1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 100/332 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1307675996; called by muse, mutect2, varscan2
- CASP8 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748087575, COSV51847309; called by muse, mutect2, varscan2
- CASP8 | c.947C>T p.S316F (on ENST00000432109 / NM_033355.3; = p.S333F on NM_001228.4) | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762734568, COSV51847534; called by muse, mutect2, varscan2
- CASR | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as CM145982, COSV56135468; called by muse, mutect2, varscan2
- CBX6 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1415829564; called by muse, mutect2, varscan2
- CBY2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); catalogued as COSV100137810, COSV60118866; called by muse, mutect2, varscan2
- CCDC106 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1329455659; called by muse, varscan2
- CCDC33 | c.1938+1G>A p.X646_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as rs755174125; called by muse, mutect2, varscan2
- CCDC33 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 73/252 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs199750365; called by muse, mutect2, varscan2
- CCDC34 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as rs762470269; called by muse, mutect2, varscan2
- CCM2L | c.1288G>A p.E430K (on ENST00000452892 / NM_001365692.1; = p.S408= on NM_080625.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764802834, COSV52948834; called by muse, mutect2, varscan2
- CD163L1 | c.3941G>T p.R1314L | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs756556844; called by muse, mutect2, varscan2
- CD1A | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141143133, COSV56861617; called by muse, mutect2, varscan2
- CD6 | c.1676G>A p.R559K | Missense Mutation (SNP) | VAF 94/523 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.291); catalogued as COSV57843641; called by muse, mutect2, varscan2
- CDAN1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.795); catalogued as rs1392168796; called by muse, mutect2, varscan2
- CDH10 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs778537078, COSV52582083; called by muse, mutect2, varscan2
- CELSR2 | c.3755C>A p.S1252Y | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV54772310; called by muse, mutect2, varscan2
- CETN1 | c.248A>G p.K83R | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1369548165; called by muse, mutect2
- CHD8 | c.6137C>G p.S2046C (on ENST00000646647 / NM_001170629.2; = p.S1767C on NM_020920.4) | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); catalogued as COSV63036522; called by muse, mutect2, varscan2
- CHRNA7 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 64/896 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs754418919, COSV60967589; called by muse, mutect2
- CLPX | c.1375C>T p.L459F | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.919); catalogued as rs199752289; called by muse, mutect2, varscan2
- CLVS2 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.654); catalogued as COSV51559200; called by muse, mutect2, varscan2
- CNTNAP5 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as rs1558769613; called by muse, mutect2, varscan2
- COA8 | c.536G>T p.R179M | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1013637978; called by muse, mutect2, varscan2
- COG5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99772327; called by muse, mutect2, varscan2
- COL19A1 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs914205322; called by muse, varscan2
- COL19A1 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201265017; called by muse, mutect2, varscan2
- COL1A2 | c.1630G>A p.G544S | Missense Mutation (SNP) | VAF 91/537 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs72658134, CM070778; called by muse, mutect2, varscan2
- COL20A1 | c.2881G>A p.E961K | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV58924717; called by muse, mutect2, varscan2
- COL24A1 | c.2364G>A p.K788= | Splice Region (SNP) | VAF 25/144 reads (17%) | catalogued as COSV100993720; called by muse, varscan2
- COL28A1 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs141928495, COSV68081743; called by muse, mutect2, varscan2
- COL6A5 | c.5589C>G p.N1863K (on ENST00000312481; = p.N1859K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/423 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV55202357; called by muse, mutect2, varscan2
- COL8A1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 80/542 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.968); catalogued as rs1559637200; called by muse, varscan2
- CORO1A | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as rs1483959987; called by muse, mutect2, varscan2
- CPNE4 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as rs1387944113, COSV70195246; called by muse, mutect2
- CRNKL1 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 35/309 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV55617940; called by muse, mutect2, varscan2
- CRX | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.125); catalogued as rs1165723137, COSV55757481; called by muse, mutect2, varscan2
- CSMD3 | c.7550-1G>A p.X2517_splice (on ENST00000297405 / NM_001363185.1; = p.X2413_splice on NM_052900.3) | Splice Site (SNP) | VAF 24/197 reads (12%) | catalogued as COSV52183110, COSV52351376; called by muse, mutect2, varscan2
- CUX2 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1172516509; called by muse, mutect2, varscan2
- CYB5R4 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV100859748, COSV63750520; called by muse, mutect2, varscan2
- CYLC2 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as rs746464948, COSV66336744; called by mutect2, varscan2
- DGKI | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs760167594, COSV55937658; called by muse, mutect2, varscan2
- DIDO1 | c.6017C>T p.P2006L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as rs1316162824; called by muse, mutect2, varscan2
- DIXDC1 | c.2032G>A p.E678K (on ENST00000440460 / NM_001037954.4; = p.E467K on NM_033425.4) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555178116, COSV59462223, COSV59462480; called by muse, mutect2, varscan2
- DLK2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1306245175; called by muse, mutect2, varscan2
- DMD | c.3031C>T p.P1011S | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as rs982781720; called by muse, mutect2, varscan2
- DMGDH | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs537451670, COSV54860381; called by muse, mutect2, varscan2
- DNAH3 | c.9797C>T p.S3266F | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777678912; called by muse, mutect2, varscan2
- DOK3 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.394); catalogued as COSV57251356; called by muse, mutect2, varscan2
- DSCAM | c.4705G>A p.D1569N | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV68030910; called by muse, varscan2
- DSE | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 57/352 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100528895; called by muse, mutect2, varscan2
- DSG3 | c.1898-1G>A p.X633_splice | Splice Site (SNP) | VAF 55/354 reads (16%) | catalogued as COSV57124246, COSV57125790; called by muse, mutect2, varscan2
- DST | c.8713C>T p.L2905F | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.035); catalogued as rs1367674779; called by muse, mutect2, varscan2
- DTNBP1 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 208/693 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100160519; called by muse, mutect2, varscan2
- EDC4 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 47/327 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs781346460; called by muse, mutect2, varscan2
- EEF2 | c.1193T>C p.I398T | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV58578947; called by muse, mutect2, varscan2
- EHD4 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV55007028; called by muse, mutect2, varscan2
- ELF5 | c.364C>T p.L122F (on ENST00000312319 / NM_198381.2; = p.L112F on NM_001422.4) | Missense Mutation (SNP) | VAF 105/353 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201472486; called by muse, mutect2, varscan2
- ETS2 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 71/482 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.918); catalogued as rs536810041, COSV100711420; called by muse, mutect2, varscan2
- EVI5L | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV54485713; called by muse, mutect2
- F12 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53692458; called by muse, mutect2, varscan2
- F12 | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as rs1337905865, COSV53691644; called by muse, mutect2, varscan2
- F13B | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV66374125; called by muse, mutect2, varscan2
- FAM20A | c.1070A>G p.N357S | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as COSV56837891; called by muse, mutect2, varscan2
- FAM47E-STBD1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as rs1359468986; called by muse, mutect2, varscan2
- FAT1 | c.2991T>G p.Y997* | Nonsense Mutation (SNP) | VAF 37/260 reads (14%) | catalogued as COSV71671738; called by muse, mutect2, varscan2
- FAT4 | c.9766G>A p.G3256S | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV58690918; called by muse, mutect2, varscan2
- FBLN2 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 23/114 reads (20%) | catalogued as COSV55483262, COSV99851815; called by muse, mutect2, varscan2
- FBN3 | c.6185-3C>T | Splice Region (SNP) | VAF 15/90 reads (17%) | catalogued as rs756088705; called by muse, mutect2, varscan2
- FBXL8 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 68/414 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1242305864; called by muse, mutect2, varscan2
- FBXL8 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 68/416 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs777480995; called by muse, mutect2, varscan2
- FBXO40 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.737); catalogued as rs775675600, COSV57521932; called by muse, mutect2, varscan2
- FDFT1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.787); catalogued as COSV55042030; called by muse, mutect2, varscan2
- FGFBP2 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs780189482, COSV52587919; called by muse, mutect2, varscan2
- FLG2 | c.4693G>A p.G1565R | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs781511680, COSV66170404; called by muse, mutect2, varscan2
- FN1 | c.4519G>A p.G1507S | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.671); catalogued as rs772920001; called by muse, mutect2, varscan2
- FOXI3 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs867424861; called by muse, mutect2, varscan2
- FOXK2 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58882033; called by muse, mutect2
- FRRS1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.308); catalogued as COSV54922805; called by muse, mutect2
- FTSJ3 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 42/276 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs200615117; called by muse, mutect2, varscan2
- G6PC | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs765059867; called by muse, mutect2, varscan2
- GABRG1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239800695, COSV54951118; called by muse, mutect2
- GABRG3 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV61509093; called by muse, mutect2, varscan2
- GAL3ST4 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 36/279 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs758657720; called by muse, mutect2, varscan2
- GAS2L2 | c.738C>T p.I246= | Splice Region (SNP) | VAF 26/136 reads (19%) | catalogued as rs1370028229; called by muse, mutect2, varscan2
- GBP7 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as rs867870028, COSV54012244; called by muse, mutect2, varscan2
- GDF9 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 65/372 reads (17%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1313744141, COSV51526304; called by muse, mutect2, varscan2
- GFRAL | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as COSV61229115; called by muse, mutect2, varscan2
- GHDC | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567648840; called by muse, mutect2, varscan2
- GIMAP6 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.159); catalogued as rs1219694439; called by muse, mutect2, varscan2
- GPAA1 | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 48/161 reads (30%) | catalogued as rs1554764209, COSV60155312; called by muse, mutect2, varscan2
- GPR15 | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs761625721; called by muse, mutect2, varscan2
- GRIK2 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs755777802, COSV59784426; called by muse, mutect2, varscan2
- GRK1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.574); catalogued as rs1481964225; called by muse, mutect2, varscan2
- GTPBP8 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); catalogued as rs1375060171; called by mutect2, varscan2
- GUCA1A | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs749286416, COSV50003745; called by muse, varscan2
- HABP2 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1223507582, COSV63638002; called by muse, mutect2, varscan2
- HDAC4 | c.1867G>A p.G623S | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs762919936, COSV61864520; called by muse, mutect2, varscan2
- HEYL | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as rs187780653; called by muse, mutect2, varscan2
- HK2 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 125/713 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51877563; called by muse, mutect2, varscan2
- HOXB1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.081); catalogued as rs1326906734; called by muse, mutect2, varscan2
- HOXD11 | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 45/373 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs868497958, COSV50912567; called by muse, mutect2, varscan2
- HS3ST4 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as COSV58806132; called by muse, varscan2
- HSDL2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 93/244 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1298551916; called by muse, mutect2, varscan2
- HUNK | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs1304676702; called by muse, mutect2, varscan2
- HYDIN | c.6986G>A p.R2329Q | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs1475681740; called by mutect2, varscan2
- IGLL5 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 158/998 reads (16%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs980130526; called by muse, mutect2, varscan2
- IKZF1 | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as rs775004468, COSV58782600; called by muse, mutect2, varscan2
- IL23R | c.1666G>A p.G556R | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61373959; called by muse, mutect2, varscan2
- INPPL1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771815535, COSV53357347; called by muse, mutect2, varscan2
- INSL6 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 47/353 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs576555591, COSV67563357; called by muse, mutect2, varscan2
- IRF2BPL | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99467833; called by muse, mutect2, varscan2
- ITGA7 | c.940G>A p.G314R (on ENST00000555728; = p.G270R on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/458 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs776086093; called by muse, mutect2, varscan2
- ITGAL | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.326); catalogued as rs768038639, COSV63323624; called by muse, mutect2, varscan2
- ITGB1 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56479587; called by muse, mutect2, varscan2
- JMJD1C | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67857543; called by muse, mutect2, varscan2
- KCNH7 | c.3202C>T p.P1068S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs139719597, COSV59812479; called by muse, mutect2, varscan2
- KCNJ6 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55724043; called by muse, mutect2, varscan2
- KCNJ8 | c.1093C>T p.L365F | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV53716548; called by muse, mutect2, varscan2
- KHDRBS2 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55430551, COSV99838612; called by muse, varscan2
- KIR2DL4 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 36/225 reads (16%) | SIFT tolerated, low confidence (0.16); catalogued as rs1023167869; called by muse, mutect2, varscan2
- KIRREL2 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV99384061; called by muse, mutect2, varscan2
- LAMA1 | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 73/521 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188310384; called by muse, mutect2, varscan2
- LCA5 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377719240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LGALS3BP | c.1039C>G p.R347G | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99431649; called by muse, mutect2, varscan2
- LGI2 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66122799; called by muse, mutect2, varscan2
- LILRB1 | c.328C>T p.P110S (on ENST00000427581; = p.P74S on NM_006669.6) | Missense Mutation (SNP) | VAF 42/640 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs1430305373, COSV61122458; called by muse, mutect2
- LRP1 | c.12286G>A p.D4096N | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54529519; called by muse, mutect2, varscan2
- LRP1B | c.13406G>A p.R4469K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV67289372; called by muse, mutect2, varscan2
- LRP1B | c.6454G>A p.G2152S | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101256383; called by muse, mutect2, varscan2
- LRP1B | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as rs772923678, COSV67209160, COSV67248203; called by muse, mutect2, varscan2
- LRP1B | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1400677373; called by muse, mutect2, varscan2
- LRP2 | c.5080C>T p.P1694S | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV55546072; called by muse, mutect2, varscan2
- LRRIQ1 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs776401325; called by muse, mutect2, varscan2
- LSM2 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1209480499; called by muse, mutect2, varscan2
- LTBP4 | c.2903G>A p.R968Q (on ENST00000308370 / NM_001042544.1; = p.R931Q on NM_003573.2) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.792); catalogued as rs776226657, COSV52581315; called by muse, mutect2, varscan2
- MAGEA10 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV54883612; called by muse, mutect2, varscan2
- MAGEC3 | c.332A>T p.K111M | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs1472222363, COSV100026309; called by muse, mutect2, varscan2
- MALRD1 | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs140205728; called by muse, mutect2, varscan2
- MAN2A2 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV64640028; called by muse, mutect2
- MAP1B | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57104230; called by muse, mutect2, varscan2
- MAP1B | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs767707942, COSV57095152; called by muse, mutect2, varscan2
- MAP3K1 | c.2316T>G p.F772L | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV68127118; called by muse, mutect2, varscan2
- MASP2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs747767865; called by muse, mutect2, varscan2
- MDGA2 | c.1871G>A p.R624Q (on ENST00000399232 / NM_001113498.2; = p.R326Q on NM_182830.4) | Missense Mutation (SNP) | VAF 44/327 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.531); catalogued as rs553082374, COSV62105261; called by muse, mutect2, varscan2
- MDGA2 | c.1300C>T p.P434S (on ENST00000399232 / NM_001113498.2; = p.P136S on NM_182830.4) | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62079322; called by muse, mutect2, varscan2
- MECOM | c.1841G>A p.G614E (on ENST00000468789 / NM_001105078.4; = p.G802E on NM_004991.4) | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.113); catalogued as rs139044661, COSV52962683; called by muse, mutect2, varscan2
- MEOX2 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV100012602; called by muse, mutect2, varscan2
- METAP1D | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as rs758821566; called by mutect2, varscan2
- MICU1 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1271588782; called by muse, mutect2, varscan2
- MRGPRX1 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57106316; called by muse, mutect2, varscan2
- MROH2B | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs377423987; called by mutect2, varscan2
- MROH5 | c.3633G>A p.W1211* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV61472730; called by muse, mutect2, varscan2
- MS4A4A | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs778720872; called by muse, mutect2, varscan2
- MST1R | c.3716A>G p.Y1239C | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200817733; called by muse, mutect2, varscan2
- MUC16 | c.24401T>A p.L8134* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as rs763386349; called by muse, mutect2, varscan2
- MUC16 | c.10097C>T p.S3366F | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.757); catalogued as COSV67488011; called by muse, mutect2, varscan2
- MYH3 | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 155/439 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as rs1318197712; called by muse, mutect2, varscan2
- MYO1A | c.-20-1G>A | Splice Site (SNP) | VAF 56/299 reads (19%) | catalogued as rs1474391063, COSV55651935; called by muse, mutect2, varscan2
- MYO3A | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752594701, COSV56327010; called by muse, mutect2, varscan2
- MYO9A | c.3899C>G p.P1300R | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100612953; called by muse, mutect2, varscan2
- MYRIP | c.1537C>T p.P513S | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as rs1559443483; called by muse, mutect2, varscan2
- MYRIP | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.778); catalogued as rs199860359, COSV56882554; called by muse, mutect2, varscan2
- NAPSA | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as rs1323636875, COSV53797848; called by muse, mutect2, varscan2
- NAV3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV57115151; called by muse, mutect2, varscan2
- NCR3LG1 | c.1096T>C p.Y366H | Missense Mutation (SNP) | VAF 77/354 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as rs1045678240; called by muse, mutect2, varscan2
- NEXMIF | c.3370C>T p.Q1124* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as COSV50084583; called by muse, mutect2, varscan2
- NFATC1 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs1555916378; called by muse, mutect2, varscan2
- NFU1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 82/463 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs1314414297; called by muse, mutect2, varscan2
- NHSL1 | c.4147C>T p.R1383* | Nonsense Mutation (SNP) | VAF 28/172 reads (16%) | catalogued as COSV100606619; called by muse, mutect2
- NLRP12 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV60743313; called by muse, varscan2
- NLRP5 | c.3263G>A p.G1088E | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV66766718; called by muse, mutect2, varscan2
- NLRP8 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1257885288, COSV52585376; called by muse, mutect2, varscan2
- NLRP8 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as COSV52594202; called by muse, mutect2, varscan2
- NMRK2 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.043); catalogued as rs745997876; called by muse, mutect2, varscan2
- NOTCH1 | c.7634C>T p.S2545F | Missense Mutation (SNP) | VAF 85/549 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV53036349; called by muse, mutect2, varscan2
- NOTCH1 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 63/414 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.233); catalogued as rs777155621; called by muse, mutect2, varscan2
- NTNG1 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV64267829, COSV64268861; called by muse, mutect2, varscan2
- NUDT9 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV56198115; called by muse, mutect2, varscan2
- NUF2 | c.123G>A p.K41= | Splice Region (SNP) | VAF 8/68 reads (12%) | catalogued as COSV54845064; called by muse, mutect2, varscan2
- NUP210 | c.3701C>T p.P1234L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs148884900, COSV54403645; called by muse, mutect2
- OR2T33 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 74/893 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs780984437; called by muse, mutect2
- OR51L1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58625582; called by muse, mutect2, varscan2
- OR6C2 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV59515933, COSV59516354; called by muse, mutect2
- OR6K6 | c.173C>T p.P58L (on ENST00000368144; = p.P34L on NM_001005184.1) | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs749532564; called by muse, mutect2, varscan2
- OR6N1 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1357886962, COSV58647960; called by muse, mutect2, varscan2
- OR7A5 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.33); catalogued as rs755231338; called by muse, mutect2, varscan2
- ORM2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 322/799 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV99407647; called by muse, mutect2, varscan2
- OTOL1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100020045; called by muse, mutect2, varscan2
- OVCH1 | c.302C>A p.T101N | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV58960382, COSV58965976; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1042G>A p.E348K (on ENST00000374531 / NM_001037293.2; = p.E380K on NM_053016.6) | Missense Mutation (SNP) | VAF 49/356 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV57133058; called by muse, varscan2
- PARK7 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 61/449 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs768782230, COSV58579460; called by muse, mutect2, varscan2
- PCDHB7 | c.2048C>T p.S683L | Missense Mutation (SNP) | VAF 92/1630 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs1554280360, COSV50772098, COSV50794392; called by muse, mutect2
- PCLO | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.164); catalogued as rs1395479813, COSV61669058; called by muse, varscan2
- PDP2 | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61240238; called by muse, mutect2, varscan2
- PEAK1 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1469492625; called by muse, mutect2, varscan2
- PEAR1 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV52771845; called by muse, mutect2, varscan2
- PEG3 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs765630906, COSV55634529; called by muse, mutect2, varscan2
- PEX5L | c.1453C>T p.H485Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.624); catalogued as COSV55848067; called by muse, mutect2, varscan2
- PFKM | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 76/444 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs183491829; called by muse, mutect2, varscan2
- PIEZO2 | c.4423G>A p.D1475N | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.612); catalogued as rs1273211700; called by muse, mutect2, varscan2
- PIK3C2B | c.3727G>T p.V1243F | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100915964; called by muse, mutect2, varscan2
- PLD1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs368807491, COSV104415999; called by muse, mutect2, varscan2
- POLR3E | c.409C>G p.P137A | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55401805; called by muse, mutect2
- POTEC | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 116/747 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs753275117, COSV62800364, COSV62801652; called by muse, mutect2, varscan2
- PPARGC1A | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs367775864; called by muse, mutect2, varscan2
- PPP1R12A | c.2965G>A p.A989T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs867607847; called by muse, varscan2
- PPP1R37 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs770334966; called by muse, mutect2, varscan2
- PPP1R3A | c.2465C>T p.T822I | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs34633103; called by muse, mutect2, varscan2
- PPP1R9A | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV56890625; called by muse, mutect2, varscan2
- PRAMEF11 | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 112/738 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.094); catalogued as rs773586166, COSV70820353; called by muse, mutect2, varscan2
- PRB1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.391); catalogued as rs766800898; called by muse, mutect2, varscan2
- PRKAG2 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs755782342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRG1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs782135730, COSV66157216; called by muse, mutect2, varscan2
- PRX | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.077); catalogued as rs771104050; called by muse, mutect2, varscan2
- PTCHD3 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.054); catalogued as COSV71256317; called by muse, mutect2, varscan2
- PTPRN2 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.058); catalogued as COSV67059096; called by muse, mutect2, varscan2
- PTPRS | c.3661C>T p.H1221Y | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV53615114; called by muse, mutect2, varscan2
- PXDNL | c.3637C>A p.P1213T | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62484260; called by muse, mutect2
- PZP | c.3647C>T p.S1216F | Missense Mutation (SNP) | VAF 47/403 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753917051, COSV54370132; called by muse, mutect2, varscan2
- QRFP | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 27/169 reads (16%) | catalogued as COSV100551045; called by muse, mutect2, varscan2
- RABEP1 | c.1491G>T p.M497I | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99336911; called by muse, mutect2, varscan2
- RAP1B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51670339; called by muse, mutect2
- RBM41 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs375097107; called by muse, mutect2, varscan2
- RBMS1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770631869; called by muse, mutect2, varscan2
- RECQL4 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 140/575 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772573389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REL | c.1250A>T p.H417L | Missense Mutation (SNP) | VAF 56/338 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV54367741; called by muse, mutect2, varscan2
- RETREG2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 74/393 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.2); catalogued as rs575011586, COSV99811489; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 40/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, varscan2
- RHBDF1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as rs746482832, COSV51954367; called by muse, mutect2, varscan2
- RIMS2 | c.1223G>A p.R408Q (on ENST00000666250 / NM_001348490.2; = p.R216Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs376489252, COSV51663807; called by muse, mutect2, varscan2
- RNF113B | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV57436457; called by muse, mutect2, varscan2
- RNF213 | c.12691C>T p.R4231W | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1344625886; called by muse, mutect2, varscan2
- ROS1 | c.3460C>T p.P1154S | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63859976; called by muse, mutect2, varscan2
- RP1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV55112087; called by muse, mutect2, varscan2
- RP1 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 93/621 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.236); catalogued as COSV55119147; called by muse, mutect2, varscan2
- RPL5 | c.172dup p.R58Kfs*55 | Frame Shift Ins (INS) | VAF 44/246 reads (18%) | catalogued as CI108641; called by mutect2, pindel, varscan2
- RYR1 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs267605463; called by muse, mutect2, varscan2
- S100B | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 55/458 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV52452656; called by muse, mutect2, varscan2
- SCN5A | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV61125061; called by muse, mutect2, varscan2
- SCNN1D | c.346C>T p.L116F (on ENST00000338555; = p.L280F on NM_001130413.4) | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.666); catalogued as rs372468691; called by muse, mutect2, varscan2
- SDC2 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs766216328; called by muse, mutect2, varscan2
- SEC63 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64600337; called by muse, mutect2, varscan2
- SELP | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.5); catalogued as rs1380753493; called by muse, mutect2, varscan2
- SEMA6A | c.1561T>C p.C521R | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1185647455; called by muse, mutect2, varscan2
- SERPINF1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as rs1431743336; called by muse, mutect2, varscan2
- SEZ6 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.983); catalogued as rs757658846; called by muse, mutect2, varscan2
- SGSM3 | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs540743923; called by muse, mutect2, varscan2
- SH3BP2 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs780642536; called by muse, mutect2, varscan2
- SI | c.2160-1G>A p.X720_splice | Splice Site (SNP) | VAF 39/294 reads (13%) | catalogued as COSV100015002; called by muse, mutect2, varscan2
- SIRT6 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs749208802; called by muse, mutect2, varscan2
- SLC6A17 | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as COSV58991457; called by muse, mutect2, varscan2
- SLCO1C1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV56878207, COSV99860050; called by muse, mutect2, varscan2
- SMU1 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 122/311 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV68139695; called by muse, mutect2, varscan2
- SMYD5 | c.13A>G p.M5V | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs760094298; called by muse, mutect2, varscan2
- SNAPC4 | c.3601C>T p.P1201S | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV100046696; called by muse, mutect2, varscan2
- SNTN | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV59538633, COSV59539478; called by muse, mutect2, varscan2
- SPATA18 | c.1479+4C>T | Splice Region (SNP) | VAF 76/528 reads (14%) | catalogued as rs1362968546; called by muse, mutect2, varscan2
- SRRT | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763989148, COSV100730056, COSV61453585; called by muse, mutect2, varscan2
- ST8SIA4 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 32/231 reads (14%) | PolyPhen probably damaging (0.988); catalogued as rs868733908, COSV51509166; called by muse, mutect2, varscan2
- STAB2 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs758782387, COSV66336179; called by muse, mutect2, varscan2
- STK31 | c.324+5G>A | Splice Region (SNP) | VAF 24/117 reads (21%) | catalogued as rs1055387417; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs148943401; called by muse, mutect2, varscan2
- STRC | c.5186G>A p.R1729Q | Missense Mutation (SNP) | VAF 58/324 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as rs765247085; called by muse, mutect2, varscan2
- SYDE2 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1351183063; called by muse, mutect2, varscan2
- SYNE2 | c.18390-7C>T | Splice Region (SNP) | VAF 56/382 reads (15%) | catalogued as COSV59973484; called by muse, mutect2, varscan2
- SYNPO2L | c.1270C>T p.R424W (on ENST00000394810 / NM_001114133.3; = p.R200W on NM_024875.5) | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs139351387, COSV100866489; called by muse, mutect2, varscan2
- TAF1L | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54261158; called by muse, mutect2, varscan2
- TAF6 | c.1769C>T p.T590I | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100612860; called by muse, mutect2, varscan2
- TAS1R2 | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 141/931 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.101); catalogued as COSV64743692; called by muse, mutect2, varscan2
- TAS2R10 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as rs747951830, COSV53701078; called by muse, mutect2, varscan2
- TBCK | c.1975G>A p.G659R (on ENST00000273980 / NM_001163436.4; = p.G596R on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369077117; called by muse, mutect2, varscan2
- TBX20 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1457366029; called by muse, mutect2, varscan2
- TDRD6 | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201364675; called by muse, mutect2, varscan2
- TERT | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV57219841; called by muse, mutect2, varscan2
- TEX19 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs1305037364, COSV100330966; called by muse, mutect2, varscan2
- THBS2 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV64682438; called by muse, mutect2, varscan2
- TIE1 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 27/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65251387; called by muse, mutect2, varscan2
- TJP1 | c.4991C>T p.P1664L | Missense Mutation (SNP) | VAF 102/429 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.249); catalogued as rs1339329686; called by muse, mutect2, varscan2
- TM4SF5 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1362787211, COSV99564777; called by muse, mutect2, varscan2
- TM9SF4 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs780304745; called by muse, mutect2, varscan2
- TMEM132B | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.487); catalogued as COSV54750826; called by muse, mutect2, varscan2
- TMEM132B | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV100170921; called by muse, mutect2, varscan2
- TMEM74B | c.433del p.R145Vfs*10 | Frame Shift Del (DEL) | VAF 39/219 reads (18%) | catalogued as COSV67891874; called by mutect2, pindel, varscan2
- TNIP3 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV50246403; called by muse, mutect2, varscan2
- TOX4 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 41/369 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1301779620; called by muse, mutect2, varscan2
- TPR | c.6433C>T p.R2145C | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1248079873, COSV100824194; called by muse, mutect2, varscan2
- TPTE | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 28/477 reads (6%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1255945263; called by muse, mutect2
- TRHR | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 42/163 reads (26%) | catalogued as COSV61233063; called by muse, mutect2, varscan2
- TRPC4 | c.2552G>A p.R851Q (on ENST00000379705 / NM_016179.4; = p.R856Q on NM_003306.3) | Missense Mutation (SNP) | VAF 44/284 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as rs772033202, COSV59021794; called by muse, mutect2, varscan2
- TTC28 | c.4180C>T p.R1394C | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs759462053, COSV67416934; called by muse, mutect2, varscan2
- TTC39C | c.377T>C p.V126A (on ENST00000317571 / NM_001135993.2; = p.V65A on NM_153211.4) | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.02); catalogued as rs977845100; called by muse, mutect2
- TTC7B | c.1274G>A p.R425H | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1446797367; called by muse, mutect2, varscan2
- TTN | c.71045T>C p.V23682A (on ENST00000591111; = p.V16258A on NM_003319.4) | Missense Mutation (SNP) | VAF 32/186 reads (17%) | PolyPhen possibly damaging (0.648); catalogued as rs781058398; called by muse, mutect2, varscan2
- TTN | c.16616G>A p.W5539* (on ENST00000591111; = p.W4612* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/222 reads (8%) | catalogued as COSV59979217; called by muse, mutect2
- UGT2B28 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs765430425, COSV59432606; called by muse, mutect2, varscan2
- UQCRC1 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs778390581, COSV52551435; called by muse, mutect2, varscan2
- VAV2 | c.680C>T p.P227L (on ENST00000371850 / NM_001134398.2; = p.P222L on NM_003371.4) | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs1291614851; called by muse, mutect2, varscan2
- VCAN | c.10109C>T p.S3370F | Missense Mutation (SNP) | VAF 62/441 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV54114125; called by muse, mutect2, varscan2
- VPS39 | c.955C>T p.L319F (on ENST00000348544 / NM_001301138.2; = p.L308F on NM_015289.5) | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58791505; called by muse, mutect2, varscan2
- VSIG10 | c.1130G>T p.C377F | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1566157977; called by muse, mutect2, varscan2
- WDFY4 | c.7079C>T p.A2360V | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV55425573, COSV55427407; called by muse, mutect2, varscan2
- WDR64 | c.1270A>G p.N424D | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1160533747; called by muse, mutect2, varscan2
- WIZ | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1455536926; called by muse, mutect2, varscan2
- XIRP2 | c.9026G>T p.R3009I (on ENST00000628543; = p.R3184I on NM_152381.6) | Missense Mutation (SNP) | VAF 45/283 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV54711414; called by muse, mutect2, varscan2
- ZBTB5 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57041621; called by muse, mutect2
- ZCCHC24 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); catalogued as rs1269382747; called by muse, varscan2
- ZFAND3 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV99765752; called by muse, mutect2, varscan2
- ZFYVE27 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 53/343 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1220516536; called by muse, mutect2, varscan2
- ZNF346 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs766730098; called by muse, mutect2, varscan2
- ZNF418 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs371520628; called by muse, mutect2, varscan2
- ZNF479 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1265087976, COSV58639990; called by muse, mutect2, varscan2
- ZNF493 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs772153973; called by muse, mutect2, varscan2
- ZNF517 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs763903563; called by muse, mutect2, varscan2
- ZNF541 | c.3911G>A p.R1304Q | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1431206091, COSV54543522; called by muse, mutect2, varscan2
- ZNF746 | c.1417C>G p.R473G | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV61407581; called by muse, mutect2, varscan2
- ZNF804A | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV100166311; called by muse, mutect2
- A2M | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA2 | c.5710C>T p.P1904S (on ENST00000614293; = p.P1874S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- AC090517.4 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ACOXL | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTN3 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ADAM28 | c.1520G>A p.G507E | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAT2 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 31/230 reads (13%) | called by muse, mutect2, varscan2
- ADGRB1 | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 76/369 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADGRG2 | c.61T>A p.F21I | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- AHCY | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 63/384 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AHNAK2 | c.8054C>T p.P2685L | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALKAL2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ANHX | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANKUB1 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANO4 | c.1701+1G>A p.X567_splice (on ENST00000392977 / NM_001286615.2; = p.X532_splice on NM_178826.4) | Splice Site (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2
- ANXA6 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AOC3 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- APOBEC3F | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOL6 | c.26G>T p.S9I | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ARAP1 | c.971C>T p.P324L (on ENST00000393609 / NM_001040118.2; = p.P79L on NM_015242.4) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ARHGAP23 | c.4220C>T p.T1407I | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ARHGAP40 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF33 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGEF33 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARID5B | c.2218A>C p.S740R | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMC2 | c.634G>T p.G212* | Nonsense Mutation (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- ARMC2 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ARSL | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ART5 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- ASB2 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.2); called by mutect2, varscan2
- ASB4 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.396); called by muse, varscan2
- ASPM | c.9359A>T p.N3120I | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ATP10A | c.3403C>T p.P1135S | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ATP13A4 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ATP2A3 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 61/529 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ATP5ME | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BHMG1 | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- BPTF | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BST2 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- BTBD8 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- C10orf71 | c.3119G>A p.R1040K | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- C10orf82 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- C12orf66 | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C19orf84 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- C4orf54 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- C4orf54 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CA4 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 60/428 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1H | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, varscan2
- CACNA1S | c.2699G>A p.R900K | Missense Mutation (SNP) | VAF 50/331 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CACNB2 | c.884A>C p.E295A (on ENST00000324631 / NM_201596.3; = p.E240A on NM_000724.4) | Missense Mutation (SNP) | VAF 71/414 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNG3 | c.634C>G p.H212D | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- CADPS2 | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADPS2 | c.1525T>G p.Y509D | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- CAND2 | c.2029G>A p.D677N (on ENST00000456430 / NM_001162499.2; = p.D584N on NM_012298.3) | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASP9 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CBLC | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBX2 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CCDC188 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC63 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CCDC73 | c.2285A>G p.N762S | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CCDC85B | c.267G>T p.Q89H | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CCPG1 | c.902C>G p.T301R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCSER2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- CCT8 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD38 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC27 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CDC42BPA | c.3584T>G p.V1195G (on ENST00000334218 / NM_001366019.2; = p.V1182G on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CDC5L | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CDH8 | c.643T>C p.Y215H | Missense Mutation (SNP) | VAF 68/340 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- CDHR3 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CDK14 | c.736T>A p.Y246N (on ENST00000380050 / NM_001287135.2; = p.Y228N on NM_012395.3) | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDK5R2 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 94/593 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CELSR2 | c.7894C>T p.P2632S | Missense Mutation (SNP) | VAF 53/310 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CEP295NL | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 45/213 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- CHD1 | c.3269G>A p.S1090N | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- CHD5 | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CHST8 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHUK | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 47/321 reads (15%) | called by muse, mutect2, varscan2
- CLECL1 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CNTNAP4 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- CNTNAP5 | c.394A>C p.N132H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL18A1 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL1A2 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 95/574 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- COL23A1 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- COL28A1 | c.3373G>A p.G1125R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- COL4A4 | c.4033A>G p.K1345E | Missense Mutation (SNP) | VAF 22/263 reads (8%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.652); called by muse, mutect2
- CPLX3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- CPNE4 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CR1 | c.6002G>A p.G2001D | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- CREB3L3 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 50/395 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CROCC2 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSN2 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CSNK1G2 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CST5 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CSTF2T | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CSTF2T | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- CTBS | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CTNNA2 | c.2189+1G>A p.X730_splice | Splice Site (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- CTNND2 | c.3611C>T p.A1204V | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CYP2C18 | c.349G>A p.G117R | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CYP2F1 | c.1083C>A p.D361E | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP4F3 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 49/306 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DACH2 | c.1177T>G p.S393A | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- DAGLB | c.682A>T p.T228S | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.24); called by muse, mutect2
- DAND5 | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- DCDC1 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DDB1 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DDX60L | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DGKB | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG1 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMD | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- DNAH5 | c.9866C>T p.P3289L | Missense Mutation (SNP) | VAF 84/607 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.5782T>G p.S1928A | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- DNAH9 | c.5783C>T p.S1928F | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAJC6 | c.42G>A p.M14I | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DRC1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DSE | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EFCAB3 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- EFCAB5 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- EFCAB6 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 47/239 reads (20%) | called by muse, mutect2, varscan2
- EIF1 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- EML3 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EML3 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ENAM | c.3370C>T p.L1124F | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ENO4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- EPGN | c.285T>G p.C95W | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHA5 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- EPPK1 | c.1126C>T p.P376S | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ERO1B | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ESPNL | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 43/233 reads (18%) | called by muse, mutect2, varscan2
- EWSR1 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- EXO5 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- F13B | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FAT2 | c.10478C>T p.A3493V | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT3 | c.2494del p.I832Ffs*29 | Frame Shift Del (DEL) | VAF 32/213 reads (15%) | called by mutect2, pindel, varscan2
- FCGBP | c.9075T>G p.N3025K | Missense Mutation (SNP) | VAF 91/1708 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- FCGBP | c.5472T>G p.N1824K | Missense Mutation (SNP) | VAF 28/613 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- FHAD1 | c.3389C>T p.S1130F | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FMN2 | c.4570G>A p.D1524N | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FOXJ1 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FOXJ1 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 40/375 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FOXR1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 54/371 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- FRMD4B | c.579C>T p.T193= | Splice Region (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- FSIP2 | c.15700C>T p.H5234Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- FYN | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRG2 | c.1174G>A p.E392K (on ENST00000361925 / NM_001375343.1; = p.E352K on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/554 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- GAD2 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 47/296 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GALNTL6 | c.924-1G>A p.X308_splice | Splice Site (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- GAPVD1 | c.4172G>A p.R1391Q (on ENST00000394104; = p.R1400Q on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/537 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- GAREM2 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GLT8D2 | c.998G>A p.S333N | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, varscan2
- GOLGA4 | c.5650T>G p.L1884V | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- GPATCH2L | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 63/454 reads (14%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- GPATCH3 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 63/353 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR158 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- GRIN2A | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM3 | c.938G>A p.S313N | Missense Mutation (SNP) | VAF 40/311 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GSX2 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HBE1 | c.247A>C p.K83Q | Missense Mutation (SNP) | VAF 261/725 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- HELQ | c.2100A>T p.Q700H | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HELZ2 | c.7859G>A p.W2620* (on ENST00000467148 / NM_001037335.2; = p.W2051* on NM_033405.3) | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- HERPUD1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HK3 | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 61/408 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMGCR | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- HOXA1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 61/363 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HOXA10 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- HTR1E | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HYDIN | c.11191T>G p.S3731A | Missense Mutation (SNP) | VAF 74/432 reads (17%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IFRD2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IFT57 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IL16 | c.1990G>A p.G664S | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IL21R | c.641G>A p.W214* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- IL2RB | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ILF3 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INPP5J | c.1701G>T p.K567N (on ENST00000331075 / NM_001284285.2; = p.K199N on NM_001002837.2) | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- INTS10 | c.1757T>C p.L586S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- IQGAP2 | c.1049A>G p.N350S | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRS2 | c.2932T>C p.Y978H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITCH | c.658G>A p.G220R (on ENST00000262650 / NM_001257137.3; = p.G179R on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ITGA6 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 82/632 reads (13%) | SIFT tolerated (0.82); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGA9 | c.3029G>A p.R1010K | Missense Mutation (SNP) | VAF 47/394 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITIH1 | c.509G>A p.R170K | Missense Mutation (SNP) | VAF 83/507 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ITPK1 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IZUMO1 | c.500-1G>A p.X167_splice | Splice Site (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- KAZN | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- KCNA1 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNJ13 | c.935A>G p.Q312R | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNK17 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KDM5D | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- KIAA1549 | c.3512T>C p.V1171A | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KIAA1614 | c.1591G>A p.G531S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.124); called by muse, mutect2
- KIF13A | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KIF6 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- KLHL15 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KMT5B | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT75 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 59/398 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- KRT76 | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KRT8 | c.594+3G>A | Splice Region (SNP) | VAF 45/328 reads (14%) | called by muse, mutect2, varscan2
- LECT2 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGALS4 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP12 | c.658T>C p.F220L | Missense Mutation (SNP) | VAF 44/267 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LRP1B | c.11431C>T p.P3811S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.11326C>T p.P3776S | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.077); called by muse, mutect2
- LRRC8B | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRK1 | c.5308C>T p.Q1770* | Nonsense Mutation (SNP) | VAF 64/498 reads (13%) | called by muse, mutect2, varscan2
- LYPD4 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MAP7D1 | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAST3 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MBD6 | c.2407-3C>A | Splice Region (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- MBIP | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MCHR2 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- MCMDC2 | c.1880-1G>A p.X627_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- MED23 | c.1699T>C p.Y567H | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MEGF10 | c.1925C>T p.T642I | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MGA | c.5717C>T p.P1906L (on ENST00000219905 / NM_001164273.1; = p.P1697L on NM_001080541.2) | Missense Mutation (SNP) | VAF 85/268 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MGAM | c.4704T>G p.C1568W | Missense Mutation (SNP) | VAF 49/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM | c.5033C>T p.P1678L | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MICAL3 | c.3833C>T p.S1278F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- MKI67 | c.2246A>G p.K749R | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MRC1 | c.2902A>G p.K968E | Missense Mutation (SNP) | VAF 68/450 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- MROH5 | c.1742A>G p.D581G | Missense Mutation (SNP) | VAF 106/406 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MRPL1 | c.77A>G p.Q26R | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MS4A1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MS4A14 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MUC15 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 82/292 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MUC16 | c.1331C>G p.A444G | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- MUC22 | c.4253C>T p.S1418F | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT deleterious (0.02); called by muse, mutect2, varscan2
- MUL1 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MYH8 | c.4341G>T p.K1447N | Missense Mutation (SNP) | VAF 87/553 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO15A | c.1513C>T p.L505F | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MYO1F | c.3+7C>T | Splice Region (SNP) | VAF 47/289 reads (16%) | called by muse, mutect2, varscan2
- MYOM1 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYT1L | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- NAT10 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAXD | c.313C>T p.H105Y | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NCF2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NDUFS1 | c.1554-23_1554-2del p.X518_splice | Splice Site (DEL) | VAF 26/271 reads (10%) | called by mutect2, pindel
- NECTIN3 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 48/267 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEGR1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- NFATC1 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP10 | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 38/563 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.119); called by muse, mutect2
- NMUR1 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 46/199 reads (23%) | called by muse, mutect2, varscan2
- NOP58 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOS2 | c.3215T>A p.L1072H | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NOTCH1 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 234/590 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- NOTCH3 | c.6320C>T p.S2107F | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NPIPB15 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 35/361 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, varscan2
- NPR1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- NRG3 | c.1597A>T p.K533* (on ENST00000404547 / NM_001370084.1; = p.K312* on NM_001165973.1) | Nonsense Mutation (SNP) | VAF 27/151 reads (18%) | called by muse, mutect2, varscan2
- NUB1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- NUTM2F | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- OGG1 | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 55/303 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- OR11H1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 49/1057 reads (5%) | called by muse, mutect2
- OR2H2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 87/312 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OR2M5 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- OR2T6 | c.153A>G p.I51M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR4F15 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- OR5I1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OTOG | c.3641G>T p.C1214F | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OXCT2 | c.940A>G p.M314V | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- P2RY10 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK4 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PAPSS2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 54/323 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PARD3B | c.2372G>A p.G791E (on ENST00000406610 / NM_001302769.2; = p.G729E on NM_152526.6) | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PBLD | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH10 | c.1792T>C p.Y598H | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH11Y | c.1840A>C p.N614H (on ENST00000400457 / NM_032973.2; = p.N603H on NM_032971.3) | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PCDH11Y | c.2507C>T p.S836F (on ENST00000400457 / NM_032973.2; = p.S825F on NM_032971.3) | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PCDH11Y | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCDH15 | c.5099C>T p.S1700F (on ENST00000644397 / NM_001354429.2; = p.S1642F on NM_001142771.2) | Missense Mutation (SNP) | VAF 68/523 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- PCDH9 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1750G>A p.V584M | Missense Mutation (SNP) | VAF 72/417 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PCDHA4 | c.2264G>A p.R755K | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- PCDHB4 | c.2150G>A p.R717K | Missense Mutation (SNP) | VAF 82/469 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PCDHGB1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCLO | c.7870C>T p.P2624S | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDZD8 | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- PIGO | c.1646T>G p.V549G | Missense Mutation (SNP) | VAF 101/225 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIWIL1 | c.2284G>A p.G762R | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLBD2 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 44/277 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PLCD3 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.355); called by muse, mutect2
- PLD1 | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PLEKHG1 | c.423C>G p.D141E | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLIN4 | c.1205G>A p.G402E (on ENST00000301286; = p.G417E on NM_001367868.2) | Missense Mutation (SNP) | VAF 65/233 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PLXNA4 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- POTEF | c.14T>C p.V5A | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- PPP1R16A | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 60/440 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.891C>A p.N297K | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.108); called by muse, varscan2
- PRAMEF4 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 109/737 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PRDM9 | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 78/478 reads (16%) | called by muse, mutect2, varscan2
- PRG4 | c.3095C>A p.T1032N | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PRODH2 | c.748G>A p.A250T (on ENST00000301175; = p.A174T on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROZ | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- PRSS56 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PTCHD4 | c.2252C>T p.S751F | Missense Mutation (SNP) | VAF 45/291 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PTCHD4 | c.1930A>G p.N644D | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- PTER | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 41/313 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- RAB39B | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAPGEF6 | c.2486A>G p.Y829C | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBIS | c.209T>G p.L70R | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- RBM15B | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RBM33 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.646); called by muse, varscan2
- RBM5 | c.1382C>T p.T461I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); called by muse, mutect2
- RFPL4AL1 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 128/1366 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); called by muse, mutect2
- RFX5 | c.1564G>A p.G522R | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RGS17 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RGS8 | c.463G>A p.E155K (on ENST00000367556 / NM_001369564.2; = p.E173K on NM_033345.3) | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBDF2 | c.2431G>C p.A811P | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- RIMS1 | c.2733T>A p.D911E | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RIMS2 | c.1454C>T p.S485L (on ENST00000666250 / NM_001348490.2; = p.S293L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 70/380 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF19A | c.1388C>T p.S463L | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RNF213 | c.8291C>T p.P2764L | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPAP1 | c.543T>C p.G181= | Splice Region (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2, varscan2
- RPRD2 | c.2621C>T p.S874F | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- S1PR2 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SAMD14 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SAMD14 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SART1 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SCAF1 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SCAP | c.2502G>A p.W834* | Nonsense Mutation (SNP) | VAF 44/257 reads (17%) | called by muse, varscan2
- SCARF1 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCRN3 | c.159G>A p.K53= | Splice Region (SNP) | VAF 33/171 reads (19%) | called by muse, mutect2, varscan2
- SF3A3 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SF3B4 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SH3BP2 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3BP4 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 39/263 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHROOM1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- SIPA1L2 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SLC17A4 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC22A1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC24A2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 90/617 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC27A4 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 99/210 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC28A2 | c.1297G>T p.V433L | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.014); called by mutect2, varscan2
- SLC7A6 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 68/521 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLCO1B3 | c.1769A>C p.Y590S | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLX4 | c.173T>G p.F58C | Missense Mutation (SNP) | VAF 90/566 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SMARCAD1 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- SMARCB1 | c.143_167del p.P48Lfs*8 | Frame Shift Del (DEL) | VAF 76/688 reads (11%) | called by mutect2, pindel
- SNCAIP | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SNORC | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SORBS2 | c.3280G>T p.G1094* (on ENST00000284776 / NM_021069.5; = p.G660* on NM_003603.6) | Nonsense Mutation (SNP) | VAF 31/247 reads (13%) | called by muse, mutect2, varscan2
- SP140L | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- SPATA18 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SPATA31D1 | c.3468A>C p.Q1156H | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SPTB | c.3322G>A p.D1108N | Missense Mutation (SNP) | VAF 125/667 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN2 | c.2135A>C p.H712P | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SPTY2D1 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRRM2 | c.872T>C p.L291S | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- STAM2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- STEAP1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRA6 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 153/697 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SUPT20HL2 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SYDE2 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYNE2 | c.12947C>T p.S4316F | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TAAR5 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 31/173 reads (18%) | called by muse, mutect2, varscan2
- TACC2 | c.6692G>A p.R2231K (on ENST00000334433; = p.R309K on NM_006997.4) | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TACR1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TANC1 | c.2816T>G p.L939R | Missense Mutation (SNP) | VAF 75/533 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TBC1D23 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- TBRG1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TEX48 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TG | c.4328G>A p.G1443E | Missense Mutation (SNP) | VAF 90/341 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- TM4SF5 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMC4 | c.1296G>A p.R432= (on ENST00000617472 / NM_001145303.3; = p.R426= on NM_144686.4) | Splice Region (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- TMCC2 | c.420C>A p.D140E | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TMEFF1 | c.832A>C p.N278H | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM132C | c.2423C>T p.P808L | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM132C | c.3016G>T p.E1006* | Nonsense Mutation (SNP) | VAF 37/202 reads (18%) | called by muse, mutect2, varscan2
- TMEM67 | c.2539C>T p.H847Y | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TMPRSS3 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- TMPRSS7 | c.2405G>A p.G802E (on ENST00000452346; = p.G676E on NM_001042575.2) | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TOX3 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 73/550 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TPD52 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF2 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 179/454 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRAF7 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAPPC10 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAPPC10 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAV7 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 72/415 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- TRAV8-3 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49B | c.685A>T p.M229L | Missense Mutation (SNP) | VAF 122/500 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM51GP | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- TRIOBP | c.3685C>T p.P1229S | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TRMT61A | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC1 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TTC6 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TTF1 | c.2379-5T>A | Splice Region (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- TTF2 | c.286-1G>A p.X96_splice | Splice Site (SNP) | VAF 13/61 reads (21%) | called by muse, varscan2
601 further variants in this file (42 protein-altering or splice-affecting, 382 silent, 177 other) are not listed here.
